Somatic mutation profile of tumor specimen TCGA-CN-6997-01A (aliquot TCGA-CN-6997-01A-11D-2012-08) from TCGA case TCGA-CN-6997, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 66.5 years (24,298 days).
Specimen TCGA-CN-6997-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b556c617-11cc-4a26-83e7-81d8d1ec0897.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-6997-10A (Blood Derived Normal), aliquot TCGA-CN-6997-10A-01D-2013-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/576482a7-597d-498d-9c3d-d73036affbed

The open-access MAF lists 138 somatic variants for this specimen: 113 protein-altering or splice-affecting, 24 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 95, Silent 24, Nonsense Mutation 7, Frame Shift Del 5, Frame Shift Ins 3, In Frame Del 1, Splice Site 1, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2D | c.15641G>A p.R5214H | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs398123729, CM105480, COSV56427001, COSV99977974; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.406C>T p.Q136* | Nonsense Mutation (SNP) | VAF 65/73 reads (89%) | hotspot (GDC flag); catalogued as CM971503, COSV52676850, COSV52715987, COSV52740951; called by muse, mutect2, varscan2
- ADCY2 | c.2558G>A p.R853H | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.534); catalogued as rs1197165990, COSV57858022; called by muse, mutect2, varscan2
- ADGRG4 | c.118G>C p.D40H | Missense Mutation (SNP) | VAF 39/48 reads (81%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.493); catalogued as COSV99796175; called by muse, mutect2, varscan2
- AGMO | c.214G>T p.A72S | Missense Mutation (SNP) | VAF 92/166 reads (55%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV100694501; called by muse, mutect2, varscan2
- ASTN2 | c.685G>A p.A229T | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); catalogued as rs182920283; called by muse, mutect2, varscan2
- ATAD2B | c.1637G>T p.G546V | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99478153; called by muse, mutect2, varscan2
- ATAD2B | c.1636G>C p.G546R | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99476716, COSV99478154; called by muse, mutect2, varscan2
- B4GALNT1 | c.1097G>A p.R366Q | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV57542808; called by muse, mutect2, varscan2
- B4GALNT2 | c.1189C>T p.L397F | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100302671, COSV55925397; called by muse, mutect2, varscan2
- BAG3 | c.140C>T p.T47I | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.441); catalogued as rs1268686377, COSV100958274; called by muse, mutect2, varscan2
- BRDT | c.1635C>A p.S545R | Missense Mutation (SNP) | VAF 29/41 reads (71%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100746530; called by muse, mutect2, varscan2
- C12orf71 | c.670A>G p.I224V | Missense Mutation (SNP) | VAF 58/139 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101460543; called by muse, mutect2, varscan2
- CABS1 | c.854T>C p.L285P | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV99909121; called by muse, mutect2, varscan2
- CADM4 | c.1063T>A p.Y355N | Missense Mutation (SNP) | VAF 94/115 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99731624; called by muse, mutect2, varscan2
- CCDC180 | c.1666G>T p.E556* | Nonsense Mutation (SNP) | VAF 92/220 reads (42%) | catalogued as COSV100827120; called by muse, varscan2
- CCDC191 | c.2017C>T p.R673W | Missense Mutation (SNP) | VAF 44/53 reads (83%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs780918643, COSV99878551; called by muse, mutect2, varscan2
- CCL1 | c.149A>C p.Y50S | Missense Mutation (SNP) | VAF 67/189 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as COSV99861813; called by muse, mutect2, varscan2
- CD33 | c.143C>T p.P48L | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV99220658; called by muse, mutect2, varscan2
- CDHR5 | c.763G>A p.G255R | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1420673313, COSV100848618; called by muse, mutect2, varscan2
- CDK8 | c.752A>G p.Q251R | Missense Mutation (SNP) | VAF 82/204 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV101037438; called by muse, mutect2, varscan2
- CEMIP2 | c.2272C>T p.R758* | Nonsense Mutation (SNP) | VAF 31/71 reads (44%) | catalogued as rs746389869, COSV65488164; called by muse, mutect2, varscan2
- CNTN5 | c.2486C>T p.S829F | Missense Mutation (SNP) | VAF 46/57 reads (81%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV54320028, COSV99679407; called by muse, mutect2, varscan2
- DDX55 | c.1373T>C p.L458P | Missense Mutation (SNP) | VAF 54/136 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as rs1203034762, COSV99434697; called by muse, mutect2, varscan2
- DOCK4 | c.1405G>A p.E469K | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs750492698, COSV101455643; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.929C>A p.A310D | Missense Mutation (SNP) | VAF 128/143 reads (90%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.991); catalogued as COSV100668747, COSV62568933; called by muse, mutect2, varscan2
- EMILIN2 | c.1533C>A p.N511K | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0.019); catalogued as COSV99598743; called by muse, mutect2, varscan2
- F5 | c.3188G>A p.R1063K | Missense Mutation (SNP) | VAF 68/206 reads (33%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.003); catalogued as COSV100889189; called by muse, mutect2, varscan2
- FLT1 | c.2444A>G p.Y815C | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99164139; called by muse, mutect2, varscan2
- G6PC2 | c.973T>A p.F325I | Missense Mutation (SNP) | VAF 24/170 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99960854; called by muse, mutect2, varscan2
- GART | c.2627G>C p.S876T | Missense Mutation (SNP) | VAF 21/28 reads (75%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV101111414; called by muse, mutect2, varscan2
- GNPAT | c.1462A>G p.I488V | Missense Mutation (SNP) | VAF 72/170 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100791667; called by muse, mutect2, varscan2
- GOLGA3 | c.1030A>G p.M344V | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs756629270, COSV99204659; called by muse, mutect2, varscan2
- GPC5 | c.1210C>T p.Q404* | Nonsense Mutation (SNP) | VAF 30/95 reads (32%) | catalogued as rs755603177, COSV100995041; called by muse, mutect2, varscan2
- GRK5 | c.1391C>T p.P464L | Missense Mutation (SNP) | VAF 80/194 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as COSV64866875; called by muse, mutect2, varscan2
- GRM3 | c.2617G>A p.D873N | Missense Mutation (SNP) | VAF 84/224 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.856); catalogued as rs369532307; called by muse, mutect2, varscan2
- GSE1 | c.511G>T p.A171S | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.43); PolyPhen benign (0.049); catalogued as COSV99496955; called by muse, mutect2, varscan2
- GSE1 | c.512C>T p.A171V | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.355); catalogued as COSV99496960; called by muse, mutect2, varscan2
- IMPG2 | c.2147C>G p.S716* | Nonsense Mutation (SNP) | VAF 14/21 reads (67%) | catalogued as COSV99516099; called by muse, mutect2, varscan2
- ITPR2 | c.2951G>A p.R984K | Missense Mutation (SNP) | VAF 64/186 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as COSV67278397; called by muse, mutect2, varscan2
- KAT5 | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 39/142 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100384002; called by muse, mutect2, varscan2
- KCNJ1 | c.985G>C p.V329L | Missense Mutation (SNP) | VAF 46/85 reads (54%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.474); catalogued as COSV100131411; called by muse, mutect2, varscan2
- KIF2B | c.1469C>A p.P490H | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.144); catalogued as COSV99275845; called by muse, mutect2, varscan2
- LAMA1 | c.6404C>T p.S2135F | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.69); catalogued as rs868433311, COSV101057107; called by muse, mutect2
- LAMA2 | c.8590G>C p.D2864H | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs554254469, COSV101370674, COSV70350559; called by muse, mutect2, varscan2
- LAMB4 | c.3723C>G p.F1241L | Missense Mutation (SNP) | VAF 53/155 reads (34%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV99224966; called by muse, mutect2, varscan2
- LRATD2 | c.302C>T p.S101L | Missense Mutation (SNP) | VAF 35/53 reads (66%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs771634972, COSV100513626, COSV100513644; called by muse, mutect2, varscan2
- LRP6 | c.4385G>C p.R1462P | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1403008956, COSV99744036; called by muse, mutect2, varscan2
- MANEAL | c.1347C>G p.I449M (on ENST00000373045 / NM_001113482.1; = p.I227M on NM_152496.2) | Missense Mutation (SNP) | VAF 47/66 reads (71%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs756158384, COSV100203949, COSV61116498; called by muse, mutect2, varscan2
- MSH4 | c.683T>C p.I228T | Missense Mutation (SNP) | VAF 30/43 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs572532242, COSV99592151; called by muse, mutect2, varscan2
- MUC16 | c.41594G>A p.R13865H | Missense Mutation (SNP) | VAF 49/88 reads (56%) | SIFT tolerated, low confidence (0.33); PolyPhen probably damaging (0.966); catalogued as rs758866622, COSV101109994; called by muse, mutect2, varscan2
- MYL12B | c.169A>G p.M57V | Missense Mutation (SNP) | VAF 104/129 reads (81%) | SIFT tolerated (0.32); PolyPhen benign (0.268); catalogued as COSV99410630; called by muse, mutect2, varscan2
- MYO3A | c.1407G>T p.L469F | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56342957; called by muse, varscan2
- MYO5B | c.3820C>T p.R1274W | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as rs199930567, COSV99545859; called by muse, mutect2, varscan2
- MYO9B | c.4204G>A p.A1402T | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.019); catalogued as rs765902826, COSV68278751; called by muse, mutect2, varscan2
- NAA20 | c.449A>G p.Y150C | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV100131772; called by muse, mutect2, varscan2
- NAIF1 | c.220G>C p.D74H | Missense Mutation (SNP) | VAF 90/106 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100895834; called by muse, mutect2, varscan2
- NAV3 | c.1331del p.P444Lfs*48 | Frame Shift Del (DEL) | VAF 30/99 reads (30%) | catalogued as COSV57088012; called by mutect2, pindel, varscan2
- NCAM2 | c.2033C>G p.T678R | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99524252; called by muse, mutect2, varscan2
- NIN | c.1957A>T p.N653Y | Missense Mutation (SNP) | VAF 83/112 reads (74%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.73); catalogued as COSV99814460; called by muse, mutect2, varscan2
- OR4C6 | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 50/69 reads (72%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as rs202011136; called by muse, mutect2, varscan2
- OR52A5 | c.707C>T p.A236V | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.58); catalogued as COSV100263273, COSV56615784; called by muse, mutect2, varscan2
- PARP6 | c.1704A>G p.E568= | Splice Region (SNP) | VAF 15/26 reads (58%) | catalogued as COSV99536285; called by muse, mutect2, varscan2
- PCDHGA12 | c.1706C>T p.T569M | Missense Mutation (SNP) | VAF 98/142 reads (69%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.144); catalogued as COSV99341416; called by muse, mutect2, varscan2
- PGAP3 | c.272A>T p.H91L | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV100328646; called by muse, mutect2, varscan2
- PHACTR3 | c.715C>T p.P239S | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.15); catalogued as COSV100732932; called by muse, mutect2, varscan2
- PI4KA | c.419C>T p.S140F | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.868); catalogued as COSV99747567; called by muse, mutect2, varscan2
- PKHD1L1 | c.5575G>T p.G1859C | Missense Mutation (SNP) | VAF 38/46 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV101006612; called by muse, varscan2
- PLCB4 | c.663T>A p.D221E | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.989); catalogued as COSV99596285; called by muse, mutect2, varscan2
- POLR2A | c.1861A>G p.I621V | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.214); catalogued as rs1364922525; called by muse, mutect2, varscan2
- PRDM9 | c.1423G>A p.A475T | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.021); catalogued as COSV99690857; called by muse, mutect2, varscan2
- ROS1 | c.5114C>T p.S1705L | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as COSV63851375, COSV63859753; called by muse, mutect2, varscan2
- SAP130 | c.1577C>G p.S526C | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.935); catalogued as COSV99385062; called by muse, mutect2, varscan2
- SERINC1 | c.1229A>G p.Y410C | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as rs1326087883, COSV100305320; called by muse, mutect2, varscan2
- SH3PXD2A | c.2636A>T p.Y879F (on ENST00000369774 / NM_001365079.1; = p.Y851F on NM_014631.2) | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.992); catalogued as COSV100280315; called by muse, mutect2, varscan2
- SLC14A2 | c.1231C>T p.L411F | Missense Mutation (SNP) | VAF 74/186 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs139770269; called by muse, mutect2, varscan2
- SLC19A2 | c.801G>T p.E267D | Missense Mutation (SNP) | VAF 60/141 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV52548007, COSV52548870; called by muse, mutect2, varscan2
- SLCO2A1 | c.1248C>G p.F416L | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.999); catalogued as COSV100189175; called by muse, mutect2, varscan2
- SPEN | c.6154A>T p.K2052* | Nonsense Mutation (SNP) | VAF 28/38 reads (74%) | catalogued as COSV65365510; called by muse, mutect2, varscan2
- STEAP4 | c.1128G>A p.W376* | Nonsense Mutation (SNP) | VAF 49/171 reads (29%) | catalogued as COSV100112656; called by muse, mutect2, varscan2
- SUPT5H | c.2449C>A p.Q817K | Missense Mutation (SNP) | VAF 30/46 reads (65%) | SIFT tolerated (0.34); PolyPhen benign (0.326); catalogued as COSV100782118; called by muse, mutect2, varscan2
- TENM4 | c.2104G>T p.G702C | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV99576875; called by muse, mutect2, varscan2
- TFEC | c.34C>G p.L12V | Missense Mutation (SNP) | VAF 58/171 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.354); catalogued as COSV55399788; called by muse, mutect2, varscan2
- THOC2 | c.1720A>G p.S574G | Missense Mutation (SNP) | VAF 70/76 reads (92%) | SIFT tolerated (0.18); PolyPhen benign (0.41); catalogued as COSV99833820; called by muse, mutect2, varscan2
- TIFA | c.158C>T p.S53F | Missense Mutation (SNP) | VAF 44/69 reads (64%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.556); catalogued as COSV100655730; called by muse, mutect2, varscan2
- TMEM132E | c.284G>A p.G95E | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100396616; called by muse, varscan2
- TMPO | c.2026G>A p.G676R | Missense Mutation (SNP) | VAF 28/298 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.945); catalogued as rs1484986772, COSV99702145; called by muse, mutect2
- TTLL4 | c.2252A>G p.Y751C | Missense Mutation (SNP) | VAF 59/84 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99293580; called by muse, mutect2, varscan2
- TTN | c.62845C>A p.P20949T (on ENST00000591111; = p.P13525T on NM_003319.4) | Missense Mutation (SNP) | VAF 40/106 reads (38%) | PolyPhen benign (0.001); catalogued as COSV100622499; called by muse, mutect2, varscan2
- TTN | c.58631T>C p.I19544T (on ENST00000591111; = p.I12120T on NM_003319.4) | Missense Mutation (SNP) | VAF 27/70 reads (39%) | PolyPhen benign (0); catalogued as rs794729473, COSV100622501; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.12076G>C p.E4026Q (on ENST00000591111; = p.E3980Q on NM_003319.4) | Missense Mutation (SNP) | VAF 54/131 reads (41%) | catalogued as COSV100622507; called by muse, mutect2, varscan2
- TUSC3 | c.863-1G>T p.X288_splice | Splice Site (SNP) | VAF 24/175 reads (14%) | catalogued as COSV101142242; called by muse, mutect2, varscan2
- UBE4A | c.2983C>T p.P995S (on ENST00000252108 / NM_001204077.2; = p.P1002S on NM_004788.4) | Missense Mutation (SNP) | VAF 137/165 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52802797; called by muse, varscan2
- UNC13A | c.1397G>T p.R466L | Missense Mutation (SNP) | VAF 116/339 reads (34%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV99409070; called by muse, mutect2, varscan2
- USP22 | c.1143C>G p.I381M | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99820397; called by muse, varscan2
- VPS13A | c.1852G>T p.A618S | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100653169; called by muse, mutect2, varscan2
- XIRP2 | c.5518G>C p.E1840Q (on ENST00000628543; = p.E2015Q on NM_152381.6) | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.251); catalogued as COSV99745531; called by muse, mutect2, varscan2
- ZC3H13 | c.913G>C p.E305Q | Missense Mutation (SNP) | VAF 8/198 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99668616; called by muse, mutect2
- ZFC3H1 | c.1113A>T p.E371D | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.967); catalogued as COSV101110634; called by muse, mutect2, varscan2
- ZNF394 | c.160C>A p.P54T | Missense Mutation (SNP) | VAF 46/101 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.36); catalogued as COSV100460310; called by muse, mutect2, varscan2
- ZNF493 | c.374C>G p.T125S | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.414); catalogued as rs1024059692, COSV100828808; called by muse, mutect2, varscan2
- ZNF559 | c.861T>G p.H287Q | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100416636; called by muse, mutect2, varscan2
- ZNF675 | c.417G>T p.M139I | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV100705124; called by muse, mutect2, varscan2
- ZNF677 | c.1079C>T p.S360L | Missense Mutation (SNP) | VAF 38/52 reads (73%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV100448087; called by muse, mutect2, varscan2
- ZNF695 | c.953A>G p.H318R | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as rs377597899; called by muse, mutect2, varscan2
- AJUBA | c.144del p.R50Efs*192 | Frame Shift Del (DEL) | VAF 99/147 reads (67%) | called by mutect2, pindel, varscan2
- ENO1 | c.620_622del p.V207del | In Frame Del (DEL) | VAF 46/72 reads (64%) | called by mutect2, pindel, varscan2
- MAP3K12 | c.2293dup p.S765Kfs*2 | Frame Shift Ins (INS) | VAF 58/162 reads (36%) | called by mutect2, pindel, varscan2
- MBD1 | c.1165_1166dup p.W390Sfs*33 (on ENST00000269468 / NM_001323950.1; = p.W334Sfs*33 on NM_002384.2) | Frame Shift Ins (INS) | VAF 36/113 reads (32%) | called by mutect2, pindel, varscan2
- PPP1R3D | c.410_413del p.I137Tfs*201 | Frame Shift Del (DEL) | VAF 21/44 reads (48%) | called by mutect2, pindel, varscan2
- USP38 | c.178del p.V60Wfs*42 | Frame Shift Del (DEL) | VAF 16/29 reads (55%) | called by mutect2, pindel, varscan2
- ZBTB18 | c.22dup p.R8Kfs*18 | Frame Shift Ins (INS) | VAF 24/63 reads (38%) | called by mutect2, pindel, varscan2
- ZNF208 | c.3528del p.G1177Afs*13 | Frame Shift Del (DEL) | VAF 8/64 reads (13%) | called by mutect2, varscan2
- BCAT1 | c.150A>C p.G50= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV99678797; called by muse, mutect2, varscan2
- BCL10 | c.558C>T p.I186= | Silent (SNP) | VAF 19/29 reads (66%) | catalogued as COSV100997817; called by muse, mutect2, varscan2
- CARMIL2 | c.1182C>A p.T394= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as COSV100576171; called by muse, mutect2, varscan2
- CCAR1 | c.1398T>A p.A466= | Silent (SNP) | VAF 36/87 reads (41%) | catalogued as COSV99771244; called by muse, mutect2, varscan2
- DDX21 | c.1173A>G p.K391= | Silent (SNP) | VAF 34/84 reads (40%) | catalogued as COSV100826537; called by muse, mutect2, varscan2
- EXPH5 | c.5784C>T p.N1928= | Silent (SNP) | VAF 50/64 reads (78%) | catalogued as COSV99761962; called by muse, mutect2, varscan2
- ITGAV | c.1155C>T p.F385= | Silent (SNP) | VAF 61/140 reads (44%) | catalogued as COSV53715879; called by muse, mutect2, varscan2
- LAD1 | c.192C>T p.S64= | Silent (SNP) | VAF 25/76 reads (33%) | catalogued as rs200025654, COSV100943900; called by muse, mutect2, varscan2
- MEX3D | c.1173C>T p.R391= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as rs760888462, COSV101183530; called by muse, varscan2
- MUC5B | c.3711G>A p.A1237= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs763926849, COSV101500586; called by muse, mutect2, varscan2
- MYH4 | c.1134A>T p.P378= | Silent (SNP) | VAF 34/107 reads (32%) | catalogued as COSV99701847; called by muse, mutect2, varscan2
- NADK | c.720G>A p.L240= | Silent (SNP) | VAF 66/88 reads (75%) | catalogued as COSV100410990; called by muse, mutect2, varscan2
- OR4C15 | c.771G>T p.G257= (on ENST00000314644; = p.G203= on NM_001001920.2) | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as rs756940164, COSV100115922; called by muse, mutect2, varscan2
- PXYLP1 | c.246C>T p.A82= | Silent (SNP) | VAF 167/200 reads (84%) | catalogued as COSV99649653; called by muse, mutect2, varscan2
- REG3A | c.109C>A p.R37= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as rs538408283, COSV100532830, COSV59409033; called by muse, mutect2, varscan2
- SACS | c.12213A>G p.E4071= | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as COSV101207564; called by muse, mutect2, varscan2
- SALL1 | c.3936C>G p.T1312= | Silent (SNP) | VAF 23/57 reads (40%) | catalogued as COSV51752606, COSV99177440; called by muse, mutect2, varscan2
- SAMD3 | c.630C>T p.F210= | Silent (SNP) | VAF 28/71 reads (39%) | catalogued as COSV100148351; called by muse, mutect2, varscan2
- SLC7A6OS | c.783A>G p.G261= | Silent (SNP) | VAF 88/199 reads (44%) | catalogued as COSV99546728; called by muse, mutect2, varscan2
- SLC9A2 | c.651C>A p.V217= | Silent (SNP) | VAF 115/274 reads (42%) | catalogued as rs1289360528, COSV52132535, COSV99296546; called by muse, mutect2, varscan2
- SLIT3 | c.3486C>T p.F1162= | Silent (SNP) | VAF 25/40 reads (63%) | catalogued as rs148625020, COSV60607017; called by muse, mutect2, varscan2
- TECTA | c.6099C>T p.Y2033= | Silent (SNP) | VAF 73/88 reads (83%) | catalogued as rs372866118; called by muse, mutect2, varscan2
- TUBGCP6 | c.3495C>T p.S1165= | Silent (SNP) | VAF 21/100 reads (21%) | catalogued as rs540310913, COSV50541265; ClinVar: likely benign; called by muse, varscan2
- WFIKKN2 | c.273C>A p.A91= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as COSV100259990; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65505184 C>T | 5'Flank (SNP) | VAF 21/76 reads (28%) | called by muse, mutect2, varscan2
